Gene-level copy-number profile of tumor specimen ALCH-B3BV-TTP1-A from ALCHEMIST case ALCH-B3BV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.0 years (24,114 days).
Specimen ALCH-B3BV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 463025a6-56b9-48d0-b443-a03ec9b3c46b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3BV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/c480f562-6c04-457c-acae-255f92803feb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 2,628; copy number 2: 52,726; copy number 3: 2,975; copy number 4: 24; copy number 5: 1; copy number 6: 3; copy number 7: 2; copy number 8: 3; copy number 11: 2; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:53,290,640–53,290,751, 1 gene (within-gene range 0–2): Y_RNA.
- chr6:73,241,314–73,310,365, 4 genes (within-gene range 0–2): KHDC1, AC019205.1, RPSAP41, EIF3EP1.
- chr9:131,258,076–131,276,510, 1 gene: FAM78A.
- chr15:25,176,832–25,178,819, 2 genes (within-gene range 0–2): SNORD115-4, SNORD115-5.
- chr15:25,191,416–25,201,404, 6 genes (within-gene range 0–2): SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17.
- chr15:25,209,918–25,218,698, 5 genes (within-gene range 0–2): SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26.
- chr16:89,873,570–89,913,627, 1 gene (within-gene range 0–3): TCF25.
- chr16:89,972,586–90,019,890, 2 genes (within-gene range 0–2): AFG3L1P, DBNDD1.
- chr19:33,207,129–33,207,639, 1 gene (within-gene range 0–1): AC008738.7.
- chr22:30,356,635–30,421,771, 2 genes (within-gene range 0–2): CCDC157, RNF215.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:1,221,651–1,230,184, 3 genes, copy number 8 (within-gene range 4–8): TPSG1, AC120498.10, TPSB2.
- chr16:1,256,059–1,259,008, 2 genes, copy number 11: TPSD1, AC120498.2.
- chr22:18,873,543–18,947,741, 6 genes, copy number 6–13: FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5.
- chr22:21,141,624–21,142,371, 1 gene, copy number 5: E2F6P2.

Autosomal genes at a single copy (total copy number 1): 2,628. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
